Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A64V, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A64V-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

A-C. Brain, left frontal mass #1-#3 an , resections: Low grade oligodendroglioma (WHO grade II).

Seen in consultation with

Fluorescence in situ hybridization (FISH) studies for 1p19q deletion have been ordered on paraffin sections and will be performed by the
For interpretation, see

ICD-O-3

Oligodendroglioma
path 9450/3
Site ④ Brain, frontal
lobe C71.1
CSF Brain, supratentorial
C71.0
JAN 5/10/13

Interpreted by
Report electronically signed I

Transcribed by:

Preliminary Frozen Section Consultation:

A. Brain, left frontal mass #1, smears: Consistent with low-grade glioma. Favor oligodendroglioma.

Intraoperative cytologic smear(s) interpretation performed by:

[page 2 of 2]
Gross Description:

A. Received fresh labeled "left frontal brain mass" is a 4.4 x 2.5 x 2.1 cm portion of brain. Smears prepared. Representative sections are submitted. Grossed by

B. Received fresh labeled "left frontal brain mass #2" is a 2.8 x 2.4 x 1.8 cm portion of brain. All submitted for permanent sections only. Grossed by

C. Received fresh within rap labeled specimen trap - left frontal brain mass" is a 3.7 x 1.4 x 1.0 cm aggregate of pink-tan soft tissue. Representative sections are submitted for permanent sections only. Grossed by

Block Summary:**Part A: Left frontal brain mass**

- 1 Lt frontal brain
- 2 Lt frontal brain 2
- 3 Lt frontal brain 3
- 4 Lt frontal brain 4
- 5 Lt frontal brain 5
- 6 Lt frontal brain 6
- 7 Lt frontal brain 7
- 8 Lt frontal brain 8
- 9 Lt frontal brain 9

Part B: Left frontal brain mass #2

- 1 Lt frontal brain mass #2-1
- 2 Lt frontal brain mass #2-2
- 3 Lt frontal brain mass #2-3
- 4 Lt frontal brain mass #2-4
- 5 Lt frontal brain mass #2-5

Part C: trap left frontal brain mass

- 1 Lt frontal brain mass 1
- 2 Lt frontal brain mass 2
- 3 Lt frontal brain mass 3

END OF REPORT

Page 2 of 2

Dual/Synchronous Primary (Note)		✓
LW 4/2/13		

Source: NCI Genomic Data Commons file fa07e9a4-cc60-461b-91f1-4dc054aba039 (TCGA-DB-A64V.9675813D-E747-4768-835C-447B53418966.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).